Somatic mutation profile of tumor specimen TCGA-DF-A2KR-01A (aliquot TCGA-DF-A2KR-01A-11D-A17W-09) from TCGA case TCGA-DF-A2KR, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3.
Specimen TCGA-DF-A2KR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e28c773-bd14-43ad-bcd2-07b65e2ec80e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DF-A2KR-10A (Blood Derived Normal), aliquot TCGA-DF-A2KR-10A-01D-A17W-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/957f9817-6d86-4fc4-a8dd-2c9dad3b5e2a

The open-access MAF lists 103 somatic variants for this specimen: 83 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 17, Splice Site 3, In Frame Del 3, Frame Shift Del 2, In Frame Ins 1, Intron 1, RNA 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.302-1G>C p.X101_splice | Splice Site (SNP) | VAF 33/37 reads (89%) | catalogued as rs80358116, CS023593, CS075078, COSV100523248, COSV58784217; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 70/84 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 43/48 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 59/66 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.3207C>A p.N1069K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as COSV100228474; called by muse, mutect2, varscan2
- A2ML1 | c.3208C>A p.Q1070K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); catalogued as COSV100228477; called by muse, mutect2, varscan2
- ACADS | c.422C>T p.T141M | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT tolerated (0.09); PolyPhen benign (0.432); catalogued as rs767874760, COSV99656608; called by muse, mutect2, varscan2
- ACRBP | c.1205C>A p.T402N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.193); catalogued as COSV99975907; called by muse, mutect2
- AKAP6 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55216527; called by muse, mutect2, varscan2
- AKNAD1 | c.2234A>G p.E745G | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV100645269; called by muse, mutect2
- ARHGEF6 | c.937C>A p.Q313K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.634); catalogued as COSV99166341; called by muse, mutect2, varscan2
- ARHGEF6 | c.936C>A p.N312K | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.9); PolyPhen benign (0.021); catalogued as COSV99166343; called by muse, mutect2, varscan2
- ARMC9 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); catalogued as rs1209730135, COSV100589399, COSV100589482; called by muse, mutect2, varscan2
- BMX | c.1267C>G p.L423V | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV100564277; called by muse, mutect2, varscan2
- CACNA1B | c.4054C>T p.L1352F | Missense Mutation (SNP) | VAF 63/77 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV53133565; called by muse, mutect2, varscan2
- CADM2 | c.397T>C p.S133P (on ENST00000407528 / NM_001167674.2; = p.S135P on NM_153184.4) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.303); catalogued as COSV101052666; called by muse, mutect2, varscan2
- CCDC122 | c.511C>G p.Q171E | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV99865797; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1066C>G p.H356D (on ENST00000357886 / NM_001365728.1; = p.H342D on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100211849; called by muse, mutect2, varscan2
- CELA3A | c.769T>C p.S257P | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99266368; called by mutect2, varscan2
- CELA3B | c.769T>C p.S257P | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100448580; called by muse, mutect2, varscan2
- CFAP61 | c.2738A>T p.D913V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99843084; called by muse, mutect2, varscan2
- CNTROB | c.2176A>G p.N726D | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV100972592; called by muse, mutect2, varscan2
- DENND2A | c.1476G>T p.E492D | Missense Mutation (SNP) | VAF 43/55 reads (78%) | SIFT tolerated (0.14); PolyPhen benign (0.1); catalogued as COSV99325491; called by muse, mutect2, varscan2
- EPB41L3 | c.2795C>T p.A932V | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100548091; called by muse, mutect2, varscan2
- EPGN | c.9G>T p.L3F | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.97); PolyPhen benign (0.007); catalogued as COSV100141341; called by muse, mutect2, varscan2
- EPHA5 | c.375A>T p.R125S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV99895855; called by muse, mutect2
- ESYT1 | c.760C>G p.L254V | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99919623; called by muse, mutect2, varscan2
- EXOC1 | c.1540-1G>C p.X514_splice | Splice Site (SNP) | VAF 10/64 reads (16%) | catalogued as rs1290729531, COSV62119551; called by muse, mutect2, varscan2
- FAT1 | c.727C>A p.L243I | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101498917; called by muse, mutect2
- FBXO47 | c.934C>A p.L312I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs949444751, COSV100960536; called by muse, mutect2, varscan2
- GATM | c.454A>G p.K152E | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101188094; called by muse, mutect2, varscan2
- GPR101 | c.830T>A p.M277K | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV53240337, COSV99981237; called by muse, mutect2, varscan2
- H3C11 | c.265G>C p.A89P | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100137816; called by muse, mutect2
- HMGN5 | c.746C>A p.A249D | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs186732408; called by mutect2, varscan2
- HTR2A | c.693T>A p.D231E | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.241); catalogued as COSV101096552, COSV66328566; called by muse, mutect2, varscan2
- JRK | c.1594C>G p.R532G | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV101401029; called by muse, mutect2, varscan2
- KCNA4 | c.1532T>A p.I511N | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100068475; called by muse, mutect2, varscan2
- KRT72 | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.034); catalogued as COSV99537029; called by muse, mutect2
- L3MBTL3 | c.363G>T p.E121D | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV100695695; called by muse, mutect2, varscan2
- MEX3B | c.1225G>A p.V409M | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT tolerated (0.23); PolyPhen benign (0.375); catalogued as COSV100313839; called by muse, mutect2, varscan2
- MLH3 | c.1582T>C p.W528R | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs761221683, COSV99469529; called by muse, mutect2, varscan2
- MLPH | c.343A>T p.I115F | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV99221720; called by muse, mutect2, varscan2
- MUC3A | c.8909C>T p.A2970V | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV100113867; called by muse, mutect2, varscan2
- MYO7A | c.1506G>T p.K502N | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as rs181126043, COSV101289022; called by muse, mutect2, varscan2
- NAALAD2 | c.284T>C p.L95P | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100427992; called by muse, mutect2, varscan2
- NCR1 | c.750T>A p.D250E | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99400733; called by muse, mutect2, varscan2
- NDUFA8 | c.320T>C p.F107S | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101056733; called by muse, mutect2, varscan2
- OR51F2 | c.22A>C p.I8L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100437871; called by muse, mutect2, varscan2
- OR6K3 | c.623C>T p.T208M (on ENST00000368146; = p.T192M on NM_001005327.2) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs781152815, COSV100933824; called by muse, varscan2
- PDK4 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 43/53 reads (81%) | SIFT tolerated (0.15); PolyPhen benign (0.073); catalogued as COSV99138727; called by muse, mutect2, varscan2
- PHF3 | c.5759G>A p.R1920H | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs755576463, COSV100012840; called by muse, mutect2, varscan2
- PUF60 | c.1597A>G p.N533D (on ENST00000526683 / NM_001362896.2; = p.N516D on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.042); catalogued as COSV100252453; called by muse, mutect2, varscan2
- RUNX3 | c.514G>C p.V172L | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100136629; called by muse, mutect2, varscan2
- SAGE1 | c.144A>T p.K48N | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV100186593; called by muse, mutect2, varscan2
- SIGLEC1 | c.950C>A p.P317H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV99163251; called by muse, mutect2, varscan2
- SLC38A8 | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100230218; called by muse, mutect2, varscan2
- SP140L | c.1159A>G p.I387V | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.077); catalogued as COSV99706675; called by muse, mutect2, varscan2
- SPTA1 | c.4520G>A p.R1507Q | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs764436700, COSV100934166; called by muse, mutect2, varscan2
- TBC1D32 | c.1805G>C p.G602A | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as rs769327826, COSV51547322, COSV99249406; called by muse, mutect2, varscan2
- THRA | c.1057G>A p.V353I | Missense Mutation (SNP) | VAF 29/35 reads (83%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as rs766284607, COSV52847465; called by muse, mutect2, varscan2
- TMEM132A | c.2632A>C p.K878Q (on ENST00000453848 / NM_178031.3; = p.K879Q on NM_017870.4) | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99133775; called by muse, mutect2, varscan2
- TRIM2 | c.719A>C p.Q240P (on ENST00000437508; = p.Q267P on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100107513; called by muse, mutect2
- UBE3B | c.1270C>G p.L424V | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.59); PolyPhen benign (0.13); catalogued as COSV99783618; called by muse, mutect2
- UBQLN2 | c.1238G>A p.S413N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100592617; called by muse, mutect2, varscan2
- UPF3B | c.746A>G p.K249R | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.681); catalogued as COSV99351938; called by muse, mutect2, varscan2
- USP3 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99165629; called by muse, mutect2, varscan2
- XPO5 | c.3140C>G p.T1047R | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV99540326; called by muse, mutect2, varscan2
- ZEB1 | c.1705C>G p.P569A | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100313570; called by muse, mutect2
- ZFHX3 | c.7451C>A p.P2484H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.275); catalogued as COSV99195124; called by muse, mutect2, varscan2
- ZFP64 | c.472G>T p.G158C | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53802654; called by muse, mutect2, varscan2
- ZMYM1 | c.3181A>T p.S1061C | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV100720886; called by muse, mutect2, varscan2
- ZNF835 | c.488A>G p.E163G | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV101606252; called by mutect2, varscan2
- ZSCAN1 | c.198G>C p.W66C | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99991291; called by muse, mutect2, varscan2
- CATIP | c.790_808del p.G264Rfs*5 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- CEBPE | c.767_807del p.E256Gfs*42 | Frame Shift Del (DEL) | VAF 14/84 reads (17%) | called by mutect2, pindel
- CRYBG2 | c.193G>T p.V65F | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DERA | c.277+3_277+7del p.X93_splice | Splice Site (DEL) | VAF 15/43 reads (35%) | called by mutect2, pindel, varscan2
- HMGN5 | c.747dup p.G250Wfs*18 | Frame Shift Ins (INS) | VAF 14/58 reads (24%) | called by mutect2, varscan2
- MROH6 | c.65_76del p.T22_E26delinsK | In Frame Del (DEL) | VAF 10/82 reads (12%) | called by mutect2, pindel
- NUCB1 | c.902_909+4del | In Frame Del (DEL) | VAF 28/41 reads (68%) | called by mutect2, pindel, varscan2
- PRAMEF6 | c.1079G>T p.C360F | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRR27 | c.369_392del p.P124_A131del | In Frame Del (DEL) | VAF 14/76 reads (18%) | called by mutect2, pindel, varscan2
- TTN | c.6450_6451insATA p.M2150_V2151insI (on ENST00000591111; = p.M2104_V2105insI on NM_003319.4) | In Frame Ins (INS) | VAF 15/27 reads (56%) | called by mutect2, pindel*, varscan2
- CCDC27 | c.1116G>A p.E372= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV99622027; called by muse, mutect2, varscan2
- CTRB2 | c.519G>T p.L173= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV100274667; called by muse, mutect2, varscan2
- DENND4B | c.1413C>T p.F471= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV100768367, COSV63410395; called by muse, mutect2, varscan2
- FLG | c.10488A>G p.G3496= | Silent (SNP) | VAF 61/223 reads (27%) | catalogued as rs1180493633, COSV100910458; called by muse, mutect2, varscan2
- GPRC6A | c.1935C>A p.A645= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV100113977; called by muse, mutect2, varscan2
- HP1BP3 | c.771A>G p.V257= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV100391521; called by muse, mutect2, varscan2
- ILVBL | c.883C>T p.L295= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV99654548, COSV99654625; called by muse, mutect2, varscan2
- MLPH | c.342G>A p.K114= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV99221718; called by muse, mutect2, varscan2
- MYBBP1A | c.3048G>T p.L1016= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV99625335; called by mutect2, varscan2
- OTOGL | c.2652C>A p.P884= (on ENST00000547103; = p.P875= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- PCDHA12 | c.1461C>T p.N487= | Silent (SNP) | VAF 127/196 reads (65%) | catalogued as COSV100247407; called by muse, mutect2, varscan2
- PHKA1 | c.1797T>A p.V599= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV100262421; called by muse, mutect2
- RICTOR | c.363A>G p.L121= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as COSV99704274; called by muse, mutect2, varscan2
- RIMS3 | c.123C>T p.T41= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as rs141237185; called by muse, mutect2, varscan2
- SERPINA6 | c.843C>T p.S281= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as rs766028190, COSV100448156; called by muse, mutect2, varscan2
- TNS2 | c.2928G>C p.P976= (on ENST00000314250 / NM_170754.4; = p.P986= on NM_015319.2) | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as rs201254888, COSV100036554; called by muse, mutect2, varscan2
- XKR6 | c.939G>A p.K313= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as COSV58657393; called by muse, mutect2
- AC024940.1 | n.3375G>C | RNA (SNP) | VAF 31/108 reads (29%) | called by muse, mutect2, varscan2
- COL3A1 | c.79+3582C>T | Intron (SNP) | VAF 7/20 reads (35%) | catalogued as COSV100482378; called by muse, mutect2, varscan2
- ZFP36L1 | c.-2G>A | 5'UTR (SNP) | VAF 16/84 reads (19%) | catalogued as rs1376990415, COSV100322419; called by muse, mutect2, varscan2
